Gene-level copy-number profile of tumor specimen ALCH-B1TP-TTP1-A from ALCHEMIST case ALCH-B1TP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,815 days).
Specimen ALCH-B1TP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb3c67a0-5b39-4dfc-abfc-9a0c9ab5a0bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/ed149d7d-a020-4dfd-8cd2-13ff074392ec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 3,859; copy number 2: 46,244; copy number 3: 7,721; copy number 4: 515; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr6:168,374,697–168,375,355, 1 gene: AL138918.1.
- chr6:170,160,606–170,163,142, 1 gene: AL596442.1.
- chr8:142,111,414–142,185,527, 2 genes: AC103758.1, MIR4472-1.
- chr15:25,172,635–25,250,940, 43 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr20:62,774,121–62,776,996, 1 gene: LINC00659.
- chr21:45,478,266–45,478,326, 1 gene (within-gene range 0–1): MIR6815.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,994,794–25,995,081, 1 gene, copy number 5: UQCRHP2.
- chr2:202,874,261–203,014,798, 4 genes, copy number 5 (within-gene range 3–5): WDR12, CARF, KRT8P52, AC010900.1.

Autosomal genes at a single copy (total copy number 1): 3,859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
